Gene-level copy-number profile of tumor specimen TCGA-LP-A7HU-01A from TCGA case TCGA-LP-A7HU, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 53.6 years (19,595 days).
Specimen TCGA-LP-A7HU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.3a0265f2-db94-4e32-bc5c-8c9bc0e9d4c3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LP-A7HU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/def5404c-fc49-4235-bd12-7a2729f42067

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 19,307; copy number 2: 28,505; copy number 3: 11,705; copy number 4: 7; copy number 7: 15; copy number 8: 263; copy number 39: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LP-A7HU-01A-11D-A33N-01): tumor purity 0.44, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:214,241,676–214,684,246, 2 genes (within-gene range 0–1): AC068051.1, RPL5P8.
- chr22:25,434,324–25,729,294, 11 genes: AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2, AL022329.1, GRK3, AL022329.2, YES1P1, RNA5SP494.
- chr22:25,756,318–25,756,669, 1 gene: AL022329.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 282 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:155,375,580–155,745,071, 1 gene, copy number 8 (within-gene range 3–8): PLCH1.
- chr3:155,449,184–160,228,213, 83 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr3:160,256,986–160,399,880, 1 gene, copy number 8 (within-gene range 3–8): IFT80.
- chr3:161,083,883–176,867,838, 178 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr3:178,960,121–179,465,328, 15 genes, copy number 7: ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7.
- chr20:31,637,912–31,723,989, 4 genes, copy number 39: COX4I2, BCL2L1, BCL2L1-AS1, ABALON.

Autosomal genes at a single copy (total copy number 1): 19,307. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
